TCGA case TCGA-B8-5551 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07aa333c-8bfb-4bdd-ad86-912c099ca0a9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 65.6 years (23,976 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 16 days.
   Pathology details: Consistent pathology review: Yes.

Follow-up (2 entries)
- Days to follow up: 15 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 16.

Molecular and laboratory tests
- Leukocytes: Normal.
- Hemoglobin: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2010.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B8-5551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-B8-5551-01A-01-TS1: Section location: Top; Percent tumor cells: 62; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 20.
  Slide TCGA-B8-5551-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 15.
- Sample TCGA-B8-5551-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B8-5551-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-B8-5551-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 4.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 16 days; disease-specific survival: no event (censored), 16 days; progression-free interval: no event (censored), 16 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B8-5551-01A-01D-1530-01): tumor purity 0.16, ploidy 2.97, whole-genome doublings 1.
